Surgical pathology report (de-identified scan), TCGA case TCGA-09-1668, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1668-01B (Primary Tumor).

[page 1 of 5]
FINAL PATHOLOGIC DIAGNOSIS

A. Omentum, omentectomy: Serous carcinoma, metastatic.

B. Uterus, cervix, fallopian tubes and ovaries; total abdominal hysterectomy and bilateral salpingo-oophorectomy:

- Cervix: Nabothian cysts.
- Endometrium: No significant pathologic abnormality.
- Myometrium: No significant pathologic abnormality.
- Serosa: No significant pathologic abnormality.
- Left ovary: Serous carcinoma, metastatic.
- Left fallopian tube: Serous carcinoma, metastatic.
- Right ovary: Serous carcinoma, grade III, FIGO stage IIIC, see comment.
- Right fallopian tube: Serous carcinoma, metastatic.
- Peritoneum: Serous carcinoma, metastatic.

C. Left peri-aortic lymph nodes, dissection: Eleven regional lymph nodes with no evidence of metastatic carcinoma (0/11).

D. Omentum, omentectomy: Serous carcinoma, metastatic.

E. Peritoneum, excision: Serous carcinoma, metastatic.

F. "Pelvic tumor," resection: Serous carcinoma, metastatic.

G. Right peri-aortic lymph nodes, dissection: Serous carcinoma, metastatic to one of five regional lymph nodes (1/5); see comment.

Page 1 of 4

H. Right pelvic lymph nodes, dissection: Serous carcinoma, metastatic to one of

fourteen regional lymph nodes (1/14); see comment.

I. Colon, resection: Serous carcinoma, metastatic to mesocolon and subserosa.

J. Sigmoid colon, epiploic fat, resection: Serous carcinoma, metastatic to adipose tissue.

COMMENT:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous carcinoma.
2. Grade of tumor: III.
3. Location of tumor: Right ovary.
4. Diameter of tumor: 2.7 cm.
5. Appearance of surface of ovary: Right ovary completely replaced by a papillary and nodular tumor.
6. Condition of capsule: Not applicable.
7. Appearance of cut surface: Solid and cystic, mainly solid.
8. Color of solid areas: Pink-tan and white-tan.

[page 2 of 5]
9. Necrosis: Focal.
10. Lymphatic/vascular invasion: Not present.
11. Sites of metastases in pelvis: Right fallopian tube, left fallopian tube, left ovary.
12. Pelvic lymph nodes: One of twelve contain metastatic carcinoma (1/12), slide A4.
13. Sites of metastases in abdomen: Abdominal peritoneum, omentum, serosa of bowel.
14. Para-aortic lymph nodes: One of sixteen lymph nodes contain metastatic carcinoma (1/16), slide G3.
15. Peritoneal cytology: Positive. Cytology accession number: [REDACTED]
16. Other significant findings: None.
17. FIGO stage: IIIC.
18. TNM stage: pT3cN1MX.

Specimen(s) Received

A:Omentum (FS)
B:Uterus, cervix, tubes and ovaries
C:Left periaortic node
D:Omentum
E:Peritoneum
F:Pelvic tumor
G:Right periaortic lymph node
H:Right pelvic lymph node
I:Colon
J:Sigmoid of ipiplocica

Intraoperative Diagnosis

FS1 (A) Omentum, omentectomy: Poorly differentiated carcinoma. [REDACTED]
[REDACTED]

Clinical History

The patient is a [REDACTED] with ovarian cancer. She undergoes total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy and lymph node dissection.

Gross Description

The specimen is received in ten parts, each labeled with the patient's name and medical record number.

Parts A-B are received fresh. Parts C-J are received in formalin.

Part A, labeled "omentum," consists of an omentum measuring 60.0 x 12.0 x 3.0 cm, containing numerous

Page 2 of 4

white, glistening, firm, rubbery nodules, consistent with metastases, mostly within the parenchyma and some on the surface, the largest measuring approximately 20.0 cm. A representative section is submitted

for frozen section 1, with the frozen section remnant submitted in cassette A1.

Portions are submitted for tissue banking and Oncotech. Additional representative sections of the metastases are submitted in cassette A2.

Part B, labeled "cervix, uterus, tubes + ovaries," consists of a uterus with bilateral fallopian tubes, the left

[page 3 of 5]
ovary and a right adnexal tumor measuring 2.7 x 2.4 x 2.0 cm that is red-tan and papillary, mostly solid with a single 0.5 cm simple cyst filled with serous fluid. No normal right ovary is identified. Multiple small, nodular and papillary growths are present on the surface of both fallopian tubes, the left ovary (0.7 cm nodule) and a continuous flap of peritoneum attached to the left adnexa. The entire specimen weighs 64.0 gm. The uterus measures 5.7 cm from fundus to cervix, 3.0 cm from cornu to cornu, 2.2 cm from anterior to posterior and is oriented by the relationship of the round ligaments to the fallopian tubes. The serosa is smooth. The uterine cavity sounds to 5.5 cm. The cervix measures 2.0 cm in length and 2.5 cm in width. The external os is fish-mouthed and measures 0.5 cm in width. The uterus and cervix are inked as follows: anterior in black and posterior in blue. The specimen is opened along the lateral borders. The transition zone is unremarkable. The endocervical mucosa is slightly polypoid. The endometrium is pink-tan, measures 1.0 mm and has no polyps. The myometrium measures 1.4 cm and contains no leiomyomas or tumor. The left fallopian tube measures 4.5 cm in length and 0.6 cm in average diameter. The fimbriae are lush. On cut section, the tube is unremarkable. The left ovary measures 1.8 x 1.1 x 1.1 cm. On cut section, the ovary is unremarkable. The flap of peritoneum attached to the left ovary measures 7.0 x 3.0 x 0.1 cm. The right fallopian tube measures 4.5 cm in length and 0.6 cm in average diameter. The fimbriae are lush. On cut section, the tube is unremarkable. Approximately 5.0 gm of the right ovary is submitted for tumor banking. Representative sections are submitted as follows:

Cassette B1: Cervix.
Cassette B2: Endomyometrium.
Cassette B3: Left ovary.
Cassette B4: Left fallopian tube and attached flap of peritoneum.
Cassette B5: Junction between right uterus and right adnexal tumor.
Cassettes B6-B8: Right adnexal tumor.
Cassette B9: Right fallopian tube.

Part C is additionally labeled "left periaortic node." It consists of a single fragment of yellow-brown fibrofatty tissue, measuring 9.0 x 1.2 x 0.8 cm, containing numerous candidate lymph nodes. The specimen is entirely submitted as follows:

Cassettes C1-C2: One third of the specimen, bisected.
Cassette C3: One third of the specimen, bisected.
Cassette C4: Remaining specimen.

Part D is additionally labeled "omentum." It consists of a single fragment of yellow-tan omentum, measuring 7.5 x 4.8 x 1.2 cm, containing a serosal implant of light-tan, papillary apparent metastatic tumor, measuring 1.5 x 0.3 x 0.3 cm. Serial sections through the omentum reveal an

[page 4 of 5]
[REDACTED]

elongated, cylindrical candidate lymph node, measuring roughly 3 cm in length x 0.4 cm in diameter. Representative sections are submitted as follows:
Cassette D1: Serosal tumor implant.
Cassette D2: Candidate lymph node, serially sectioned.
Part E is additionally labeled "peritoneum." It consists of multiple flat fragments of purple-tan, rubbery, membranous soft tissue, measuring roughly 6 x 6 x 0.8 cm in aggregate. The peritoneal surface has dozens of purple-tan to light-tan, smooth-to-slightly papillary nodules. Representative sections are submitted in cassette E1.
Part F is additionally labeled "pelvic tumor." It consists of a single fragment of light-tan, irregular, papillary soft tissue, measuring 2.0 x 2.0 x 1.5 cm. The specimen is friable on sectioning. A representative section is submitted in cassette F1.

Page 3 of 4

Part G is additionally labeled "right periaortic node." It consists of two roughly cylindrical fragments of purple-tan, irregular soft tissue, each measuring 3 x 1.8 x 0.6 cm and each containing multiple candidate lymph nodes. The specimen is entirely submitted as follows:
Cassettes G1-G2: One fragment, bisected, with the largest node trisected.
Cassettes G3-G4: Other fragment, bisected.
Part H is additionally labeled "right pelvic node." It consists of five fragments of yellow-tan fatty tissue, measuring 5 x 3.5 x 1.5 cm in aggregate, containing multiple candidate lymph nodes, measuring up to 2.7 cm. The specimen is entirely submitted as follows:
Cassettes H1-H2: Two lymph nodes, one inked black, both bisected.
Cassette H3: Two lymph nodes.
Cassette H4: Remaining lymph nodes.
Cassettes H5-H6: Fat.
Part I is additionally labeled "colon." It consists of an unoriented loop of colon, measuring 14.8 cm in length along the tinea coli x approximately 4.0 cm in diameter, with white-tan tumor nodules and plaques almost diffusely involving the serosa and mesentery. The margins are inked black, and the specimen is opened, revealing unremarkable bowel wall and mucosa. Representative sections are submitted as follows:
Cassette I1: Colon margins, perpendicular sections.
Cassette I2: Mesenteric margin.
Cassette I3: Central section of bowel.
Part J is additionally labeled "sigmoid of ipiplocica [sic]." It consists of a single crescent-shaped fragment of yellow-brown fat, measuring 9 x 1.8 x 0.5 cm, containing a few white, translucent nodules, measuring up to 0.2 cm, and plaques, consistent with metastases. Representative sections are submitted in cassette J1.

[page 5 of 5]
[REDACTED]

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file 1948e296-908e-48ae-b8f7-0a38720e7f83 (TCGA-09-1668.7740B3EC-1D81-4408-BE9E-45CCD7E91B3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).